Somatic mutation profile of tumor specimen ce1e5dfc-2ef1-4633-af93-5ea4d9 (aliquot ce1e5dfc-2ef1-4633-af93-5ea4d9_D6) from CPTAC case 17OV039, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen ce1e5dfc-2ef1-4633-af93-5ea4d9: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5824e302-4d7a-4d79-ae1f-755278c81c8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0dadc0a2-6f5f-4fe1-81bf-62a50a (Blood Derived Normal), aliquot 0dadc0a2-6f5f-4fe1-81bf-62a50a_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f3ed513-2b8f-46cc-bbac-1d63c784999d

The open-access MAF lists 126 somatic variants for this specimen: 86 protein-altering or splice-affecting, 23 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 23, Intron 10, RNA 3, Nonsense Mutation 3, Splice Site 3, Splice Region 2, Frame Shift Del 2, 3'Flank 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 93/194 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AMDHD2 | c.629-1G>A p.X210_splice | Splice Site (SNP) | VAF 47/335 reads (14%) | catalogued as COSV53552570; called by muse, mutect2, varscan2
- CDK12 | c.1462del p.E488Rfs*8 | Frame Shift Del (DEL) | VAF 173/257 reads (67%) | catalogued as COSV71001177; called by mutect2, pindel, varscan2
- CLIC1 | c.681G>T p.E227D | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs766229538; called by muse, mutect2, varscan2
- COBL | c.3569C>T p.S1190L | Missense Mutation (SNP) | VAF 37/429 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs140576062; called by muse, mutect2
- DLG2 | c.2450A>C p.K817T | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV99712915; called by muse, mutect2, varscan2
- DLK1 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1398459259; called by muse, mutect2, varscan2
- DUSP10 | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 78/528 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.848); catalogued as rs369421974; called by muse, mutect2, varscan2
- GLDN | c.474G>T p.L158F | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV59089775; called by muse, mutect2, varscan2
- GPR12 | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs766031054, COSV101197969, COSV67344656, COSV67344765; called by muse, varscan2
- H3C12 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.204); catalogued as rs1199392510; called by muse, mutect2, varscan2
- IK | c.1658A>G p.K553R | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs765492006; called by muse, mutect2, varscan2
- KIF21A | c.715G>C p.V239L | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.08); catalogued as rs1398697802; called by muse, mutect2, varscan2
- LAMA1 | c.7114G>T p.G2372* | Nonsense Mutation (SNP) | VAF 38/506 reads (8%) | catalogued as COSV67532573; called by muse, mutect2
- MAP1A | c.5555T>A p.L1852H | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as rs1245276394; called by muse, mutect2, varscan2
- MS4A14 | c.1738C>A p.Q580K | Missense Mutation (SNP) | VAF 30/367 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV55736477; called by muse, mutect2
- NLGN3 | c.551C>T p.A184V (on ENST00000358741 / NM_181303.2; = p.A164V on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.028); catalogued as rs759459838, COSV62444326; called by muse, mutect2, varscan2
- NSMCE3 | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.127); catalogued as rs757473696; called by muse, mutect2, varscan2
- OPN4 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759430131; called by muse, mutect2
- ORAI2 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 124/374 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs376890782; called by muse, mutect2, varscan2
- PARD3 | c.1283C>T p.S428L | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs141769427; called by muse, mutect2, varscan2
- PCNX4 | c.1943-1G>A p.X648_splice (on ENST00000406854 / NM_001330177.2; = p.X414_splice on NM_022495.5) | Splice Site (SNP) | VAF 11/65 reads (17%) | catalogued as COSV58306500; called by muse, varscan2
- PHIP | c.4096G>A p.V1366I | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as rs202187736, COSV99244619; called by muse, mutect2, varscan2
- PITPNM2 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752872683, COSV54899347; called by muse, mutect2, varscan2
- PSD3 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 109/463 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as rs777926512; called by muse, mutect2, varscan2
- RAPGEF3 | c.1886G>C p.R629P (on ENST00000389212; = p.R587P on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50216960; called by muse, mutect2
- RDH8 | c.165C>T p.V55= (on ENST00000651512; = p.V35= on NM_015725.4) | Splice Region (SNP) | VAF 11/56 reads (20%) | catalogued as rs200198658, COSV50674909, COSV50677326, COSV99408671; called by muse, mutect2, varscan2
- RPL27A | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 62/239 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as rs760749315, COSV58484801; called by muse, mutect2, varscan2
- SLC38A2 | c.1192G>A p.V398I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV56745717; called by muse, mutect2
- SNRK | c.1376T>C p.M459T | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1477257719; called by muse, mutect2, varscan2
- TBX18 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 47/161 reads (29%) | catalogued as rs1384411524, COSV100858519; called by muse, mutect2, varscan2
- TMX3 | c.593C>G p.P198R | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55183831; called by muse, mutect2, varscan2
- CCS | c.313T>C p.F105L | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.516); called by muse, mutect2
- CD1E | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CHD6 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 43/292 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- CHD7 | c.7340C>T p.A2447V | Missense Mutation (SNP) | VAF 138/454 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, varscan2
- CKMT1A | c.1216A>G p.I406V | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- CRTAC1 | c.859_880delinsCT p.D287Lfs*6 | Frame Shift Del (DEL) | VAF 11/79 reads (14%) | called by pindel, varscan2*
- CUBN | c.5462C>T p.S1821F | Missense Mutation (SNP) | VAF 61/295 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- DENND1C | c.1733G>C p.R578T | Missense Mutation (SNP) | VAF 17/240 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.535); called by muse, mutect2
- EDC4 | c.1019G>A p.W340* | Nonsense Mutation (SNP) | VAF 38/362 reads (10%) | called by muse, mutect2
- IKBIP | c.120G>C p.W40C | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- IL15RA | c.761G>A p.S254N | Missense Mutation (SNP) | VAF 40/552 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.014); called by muse, mutect2
- ISOC1 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1210 | c.2210T>A p.V737D | Missense Mutation (SNP) | VAF 153/432 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- KLRD1 | c.152A>C p.E51A | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.638); called by muse, mutect2
- KRTAP1-5 | c.125C>T p.T42I | Missense Mutation (SNP) | VAF 129/1056 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- LGALS9B | c.61A>T p.I21F | Missense Mutation (SNP) | VAF 27/536 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LIN7A | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP6 | c.3361T>G p.S1121A | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- MAU2 | c.1687C>G p.Q563E | Missense Mutation (SNP) | VAF 42/360 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- MIPOL1 | c.1196C>A p.A399E | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- MRPS5 | c.788A>G p.D263G | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.078); called by muse, mutect2
- MTUS2 | c.1676G>C p.S559T | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MUC17 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- MXRA5 | c.6431C>G p.A2144G | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- OR6F1 | c.712T>A p.F238I | Missense Mutation (SNP) | VAF 39/361 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OSBPL3 | c.97-1G>T p.X33_splice | Splice Site (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- PCDH9 | c.805A>C p.T269P | Missense Mutation (SNP) | VAF 93/506 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- PDE5A | c.1319C>A p.T440K | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0.049); called by muse, mutect2
- PGLYRP2 | c.1046T>C p.V349A | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- POTEA | c.209A>T p.H70L | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRG2 | c.661T>A p.S221T | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- RCOR3 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RILP | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- RNFT1 | c.643T>A p.S215T | Missense Mutation (SNP) | VAF 76/124 reads (61%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SEC24D | c.1480C>G p.L494V | Missense Mutation (SNP) | VAF 6/160 reads (4%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.999); called by muse, mutect2
- SECISBP2L | c.2092G>T p.V698F (on ENST00000559471 / NM_001193489.2; = p.V653F on NM_014701.4) | Missense Mutation (SNP) | VAF 14/233 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2
- SIGLEC12 | c.742T>C p.F248L (on ENST00000291707 / NM_053003.4; = p.F130L on NM_033329.2) | Missense Mutation (SNP) | VAF 60/274 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SRGAP2 | c.1872T>C p.H624= (on ENST00000624873 / NM_001170637.4; = p.H625= on NM_015326.5 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 31/179 reads (17%) | called by muse, mutect2, varscan2
- TAB3 | c.770C>A p.P257Q | Missense Mutation (SNP) | VAF 103/316 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- TACC3 | c.1243T>G p.F415V | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.052); called by muse, mutect2
- TBC1D9 | c.3377T>A p.L1126H | Missense Mutation (SNP) | VAF 54/301 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TDRD15 | c.2092G>T p.A698S | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TGM6 | c.2066C>T p.P689L | Missense Mutation (SNP) | VAF 88/464 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TMEM121B | c.1687G>A p.G563R | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- TTN | c.9062T>A p.L3021H (on ENST00000591111; = p.L2975H on NM_003319.4) | Missense Mutation (SNP) | VAF 32/486 reads (7%) | PolyPhen probably damaging (0.912); called by muse, mutect2
- VSTM1 | c.413T>C p.V138A | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR5B | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 91/437 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- WNK3 | c.5000T>C p.I1667T | Missense Mutation (SNP) | VAF 66/296 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- YTHDC1 | c.1390C>T p.P464S (on ENST00000344157 / NM_001031732.4; = p.P446S on NM_133370.4) | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.141); called by muse, mutect2
- ZMYM4 | c.2476A>G p.S826G | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ZNF292 | c.1187T>A p.I396N | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ZNF445 | c.187T>A p.Y63N | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF536 | c.2270G>C p.G757A | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2
- ZNF732 | c.569C>A p.A190D | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- AIFM3 | c.822C>T p.D274= | Silent (SNP) | VAF 40/389 reads (10%) | catalogued as rs569509463, COSV59004979; called by muse, mutect2, varscan2
- CASKIN1 | c.2466C>T p.S822= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs1033382934; called by muse, mutect2
- DHX36 | c.2382G>T p.L794= | Silent (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
- GABRB3 | c.675C>T p.F225= | Silent (SNP) | VAF 57/533 reads (11%) | catalogued as rs201004195; ClinVar: likely benign; called by muse, mutect2, varscan2
- HAS1 | c.516C>A p.P172= | Silent (SNP) | VAF 45/161 reads (28%) | called by muse, mutect2, varscan2
- LAMB4 | c.1539T>C p.A513= | Silent (SNP) | VAF 38/129 reads (29%) | called by muse, mutect2, varscan2
- LGALS3BP | c.882G>A p.E294= | Silent (SNP) | VAF 50/223 reads (22%) | called by muse, mutect2, varscan2
- LHFPL1 | c.432C>T p.S144= | Silent (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2, varscan2
- NCOR2 | c.6024G>A p.P2008= | Silent (SNP) | VAF 14/200 reads (7%) | catalogued as rs745657498, COSV62296052; called by muse, mutect2
- NOL6 | c.2451G>T p.S817= | Silent (SNP) | VAF 75/239 reads (31%) | called by muse, mutect2, varscan2
- OR8B2 | c.498C>T p.L166= | Silent (SNP) | VAF 42/196 reads (21%) | catalogued as rs758409458, COSV100899456; called by muse, mutect2, varscan2
- P2RY6 | c.918G>A p.K306= | Silent (SNP) | VAF 93/304 reads (31%) | called by muse, mutect2, varscan2
- PDE1B | c.1014C>T p.C338= | Silent (SNP) | VAF 84/339 reads (25%) | called by muse, mutect2, varscan2
- PKD1 | c.4485C>T p.P1495= | Silent (SNP) | VAF 157/628 reads (25%) | catalogued as rs578064441; called by muse, mutect2, varscan2
- RHOXF2 | c.357G>A p.S119= | Silent (SNP) | VAF 100/1035 reads (10%) | catalogued as rs782048832, COSV65047646; called by muse, mutect2
- RNF26 | c.153G>A p.L51= | Silent (SNP) | VAF 111/493 reads (23%) | catalogued as rs947333387; called by muse, mutect2, varscan2
- SLC5A9 | c.297A>C p.T99= | Silent (SNP) | VAF 29/388 reads (7%) | called by muse, mutect2
- SLC6A19 | c.1416C>T p.I472= | Silent (SNP) | VAF 75/992 reads (8%) | called by muse, mutect2
- SLIT1 | c.3198G>T p.G1066= | Silent (SNP) | VAF 26/146 reads (18%) | called by mutect2, varscan2
- SPSB3 | c.906G>A p.P302= | Silent (SNP) | VAF 38/422 reads (9%) | catalogued as rs373221053; ClinVar: likely benign; called by muse, mutect2
- TEX13A | c.468G>A p.G156= | Silent (SNP) | VAF 38/181 reads (21%) | called by muse, mutect2, varscan2
- TUBA3C | c.727C>A p.R243= | Silent (SNP) | VAF 72/357 reads (20%) | called by muse, mutect2, varscan2
- ZNF79 | c.1056G>A p.Q352= | Silent (SNP) | VAF 31/386 reads (8%) | called by muse, mutect2
- AC026410.1 | n.556C>G | RNA (SNP) | VAF 34/135 reads (25%) | called by muse, mutect2, varscan2
- AK2 | c.*4167G>C | 3'UTR (SNP) | VAF 42/619 reads (7%) | called by muse, mutect2
- ALDH1L1 | c.128-905G>A | Intron (SNP) | VAF 46/284 reads (16%) | called by muse, mutect2
- ANKRD30B | c.2313+1546A>G | Intron (SNP) | VAF 27/44 reads (61%) | called by muse, mutect2, varscan2
- ARHGAP4 | c.682-368C>A | Intron (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- DSCR4 | n.444C>T | RNA (SNP) | VAF 34/122 reads (28%) | catalogued as rs141636283; called by muse, mutect2, varscan2
- ENPP2 | c.480-725G>T | Intron (SNP) | VAF 23/141 reads (16%) | called by muse, mutect2, varscan2
- EPSTI1 | chr13:42888365 C>A | 3'Flank (SNP) | VAF 17/200 reads (9%) | catalogued as rs763326690, COSV100552604, COSV58048949; called by muse, mutect2
- HDAC8 | c.437+129C>G | Intron (SNP) | VAF 10/174 reads (6%) | called by muse, mutect2
- HNRNPA3P1 | n.713G>T | RNA (SNP) | VAF 35/274 reads (13%) | catalogued as rs777491590; called by muse, mutect2, varscan2
- LAMA4 | c.195+67T>C | Intron (SNP) | VAF 76/451 reads (17%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.573+1748G>C | Intron (SNP) | VAF 30/214 reads (14%) | called by muse, mutect2, varscan2
- MARVELD3 | chr16:71644834 G>T | 3'Flank (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- RTF2 | c.646+20C>A | Intron (SNP) | VAF 72/162 reads (44%) | called by muse, mutect2, varscan2
- SNX5 | c.51+5534C>G | Intron (SNP) | VAF 42/177 reads (24%) | catalogued as COSV66698684; called by muse, mutect2, varscan2
- THRB | c.284-12553G>A | Intron (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- TTC6 | chr14:37795307 G>A | 5'Flank (SNP) | VAF 12/89 reads (13%) | catalogued as rs1271537961; called by muse, mutect2, varscan2
